Somatic mutation profile of tumor specimen C3N-00204-02 (aliquot CPT0084630012) from CPTAC case C3N-00204, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.0 years (23,017 days).
Specimen C3N-00204-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f56f6595-2b02-4547-bbf9-53517ece8f46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00204-31 (Blood Derived Normal), aliquot CPT0085320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce474ae3-c514-4677-8ecc-8d1fc13dea8d

The open-access MAF lists 1,063 somatic variants for this specimen: 734 protein-altering or splice-affecting, 226 silent, 103 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 616, Silent 226, Intron 43, Nonsense Mutation 43, Frame Shift Del 27, RNA 21, 3'UTR 16, Splice Site 16, 5'UTR 14, Frame Shift Ins 13, Splice Region 10, In Frame Del 5.

Variants (750 of 1,063; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 68/360 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 47/424 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PDX1 | c.188del p.P63Rfs*60 | Frame Shift Del (DEL) | VAF 88/371 reads (24%) | catalogued as rs193929377; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC2A10 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 54/930 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs864309480, CM080545; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 167/287 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM32 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1361862452, COSV65952189, COSV65952265; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs759321450; called by muse, mutect2, varscan2
- ADGRA1 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV74142982; called by muse, mutect2, varscan2
- ADHFE1 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99397875; called by muse, mutect2, varscan2
- AFDN | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV60055445, COSV60060247; called by muse, mutect2
- AHNAK2 | c.2731G>A p.G911S | Missense Mutation (SNP) | VAF 48/546 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.436); catalogued as rs1161726288, COSV60921708; called by muse, mutect2
- AKAP4 | c.859C>A p.R287S | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.238); catalogued as COSV62074815; called by muse, mutect2, varscan2
- AKR1B1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 136/839 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99035877; called by muse, mutect2, varscan2
- AKR1D1 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 119/684 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as COSV54336408; called by muse, mutect2, varscan2
- AMER1 | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100365058; called by muse, mutect2, varscan2
- APOBEC3F | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157568843; called by muse, mutect2
- APOBEC3G | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.836); catalogued as rs1416990881; called by muse, mutect2, varscan2
- ARHGAP6 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs899747979, COSV57291137; called by muse, mutect2
- ATP10A | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 42/306 reads (14%) | catalogued as COSV63515139; called by muse, mutect2, varscan2
- BCAR1 | c.1450del p.A484Pfs*218 | Frame Shift Del (DEL) | VAF 22/206 reads (11%) | catalogued as COSV50810745; called by mutect2, pindel, varscan2
- BMP3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV51084773; called by muse, mutect2
- C16orf90 | c.245C>A p.P82Q (on ENST00000399645 / NM_001353385.2; = p.P73Q on NM_001080524.2) | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.085); catalogued as COSV68714720; called by muse, mutect2, varscan2
- C8A | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs141666945, COSV63485866; called by muse, mutect2, varscan2
- CACNA1A | c.4591G>T p.E1531* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV64212211; called by muse, mutect2
- CADM1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 178/428 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.34); catalogued as rs745679451; called by muse, varscan2
- CCKAR | c.973T>A p.C325S | Missense Mutation (SNP) | VAF 168/586 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211884553; called by muse, mutect2, varscan2
- CD44 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1206166460; called by muse, mutect2
- CDH18 | c.999+1G>T p.X333_splice | Splice Site (SNP) | VAF 60/135 reads (44%) | catalogued as COSV99932370; called by muse, varscan2
- CDK4 | c.753dup p.R252Qfs*12 | Frame Shift Ins (INS) | VAF 44/252 reads (17%) | catalogued as rs754187815; called by mutect2, varscan2
- CDX4 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV65171704; called by muse, mutect2, varscan2
- CFAP94 | c.885G>C p.E295D (on ENST00000320267 / NM_001352064.2; = p.E301D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/500 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs996834091; called by muse, mutect2, varscan2
- CFAP99 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 61/224 reads (27%) | catalogued as rs1421242032, COSV72648575; called by muse, mutect2, varscan2
- CMAS | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1384085163; called by muse, mutect2, varscan2
- CMYA5 | c.5646G>T p.M1882I | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV71409447; called by muse, mutect2
- CNTLN | c.984-2A>T p.X328_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as rs1183675915; called by muse, mutect2
- CNTN4 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 282/460 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV61867845; called by muse, mutect2, varscan2
- COL11A1 | c.2282C>A p.P761H | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100617865, COSV62171984; called by muse, mutect2, varscan2
- COL3A1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.875); catalogued as COSV58598349; called by muse, mutect2
- COL9A3 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 98/517 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.978); catalogued as rs1440423945, COSV58987314; called by muse, mutect2, varscan2
- COMT | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 58/526 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs555126080, COSV52890089; called by muse, mutect2, varscan2
- CSE1L | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 173/469 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99522068; called by muse, mutect2, varscan2
- CSMD3 | c.4710G>T p.Q1570H (on ENST00000297405 / NM_001363185.1; = p.Q1466H on NM_052900.3) | Missense Mutation (SNP) | VAF 370/658 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV52298115; called by muse, mutect2, varscan2
- CSNK1E | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100725023; called by muse, mutect2, varscan2
- CTR9 | c.1703G>T p.W568L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV63727901; called by muse, mutect2, varscan2
- CYTIP | c.279+3G>T | Splice Region (SNP) | VAF 166/406 reads (41%) | catalogued as COSV51632751; called by muse, mutect2, varscan2
- DCN | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 27/470 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1011057527; called by muse, mutect2
- DENND2A | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99327178; called by muse, mutect2
- DGKI | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99935198; called by muse, mutect2, varscan2
- DHX36 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as rs1345725102; called by muse, mutect2
- DLC1 | c.3880C>A p.R1294S (on ENST00000276297 / NM_001348081.2; = p.R857S on NM_006094.5) | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV52289738, COSV52306340; called by muse, varscan2
- DLC1 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.444); catalogued as COSV99363182; called by muse, mutect2
- DMD | c.5704A>G p.S1902G | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as CX163698; called by muse, mutect2, varscan2
- DOK6 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV66930323; called by muse, mutect2
- DPP10 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 111/236 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs202170246, COSV59695021; called by muse, mutect2, varscan2
- DUSP26 | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 88/519 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs753031331; called by muse, mutect2, varscan2
- EIF3B | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs368514580; called by muse, mutect2, varscan2
- EPN2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 46/1894 reads (2%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1567853577; called by muse, mutect2
- FAM135B | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 217/413 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs370285922; called by muse, mutect2, varscan2
- FAM135B | c.629T>C p.L210S | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266395722; called by muse, mutect2, varscan2
- FAM47C | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100792488; called by muse, mutect2, varscan2
- FAM71D | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs763782646, COSV61295060; called by muse, mutect2, varscan2
- FAT1 | c.4709G>T p.R1570L | Missense Mutation (SNP) | VAF 192/342 reads (56%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV71675319; called by muse, mutect2, varscan2
- FBN2 | c.4286C>A p.P1429Q | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV99325827, COSV99331136; called by muse, mutect2, varscan2
- FCGBP | c.2536C>A p.R846S | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs977726619; called by muse, mutect2, varscan2
- FCSK | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1035978768; called by muse, mutect2
- FGFR2 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 141/383 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs764959117, COSV60652684; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- FOXA3 | c.977del p.G326Afs*47 | Frame Shift Del (DEL) | VAF 49/440 reads (11%) | catalogued as rs1425262141; called by mutect2, pindel, varscan2
- FRMPD1 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs758980439, COSV66700495; called by muse, mutect2, varscan2
- GALR3 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as rs1236455611, COSV99968023; called by muse, mutect2, varscan2
- GBX2 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100103664; called by muse, mutect2
- GLG1 | c.1316A>T p.E439V | Missense Mutation (SNP) | VAF 35/484 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52665643; called by muse, mutect2
- GLYATL2 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs763980765; called by muse, mutect2, varscan2
- GP9 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 143/699 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775994327; called by muse, mutect2, varscan2
- GPLD1 | c.156G>C p.L52= | Splice Region (SNP) | VAF 68/281 reads (24%) | catalogued as rs867752373; called by muse, mutect2, varscan2
- GPX3 | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV66313065; called by muse, mutect2
- GRM8 | c.768A>T p.E256D | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs377649502; called by muse, mutect2
- GSPT2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as rs781925454; called by muse, mutect2, varscan2
- H2BC9 | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 43/516 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as rs1379959298, COSV55101236; called by muse, mutect2
- H2BW2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1199937421; called by muse, mutect2, varscan2
- HAL | c.1505C>A p.T502K | Missense Mutation (SNP) | VAF 195/621 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781581441, COSV54120752; called by muse, mutect2, varscan2
- HCN1 | c.2027G>C p.S676T | Missense Mutation (SNP) | VAF 56/670 reads (8%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV57521709; called by muse, mutect2
- HDGFL1 | c.444C>G p.S148R | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.023); catalogued as COSV57751353, COSV57752503; called by muse, mutect2, varscan2
- HELZ2 | c.3638C>T p.P1213L (on ENST00000467148 / NM_001037335.2; = p.P644L on NM_033405.3) | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs772356088, COSV100915603; called by muse, mutect2, varscan2
- HRG | c.781C>A p.H261N | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV51645559; called by muse, mutect2
- HS3ST5 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100451138; called by muse, mutect2
- IGHA1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 33/438 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.04); catalogued as rs1182030460; called by muse, mutect2
- IL7R | c.876A>G p.K292= | Splice Region (SNP) | VAF 291/887 reads (33%) | catalogued as COSV57409413; called by muse, mutect2, varscan2
- IRS2 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 211/327 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV101019423; called by muse, mutect2, varscan2
- ITGAD | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs200809631; called by muse, mutect2, varscan2
- ITIH5 | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53674818; called by muse, mutect2
- KCTD8 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV63594562; called by muse, varscan2
- KDM5C | c.3301-1G>A p.X1101_splice | Splice Site (SNP) | VAF 65/480 reads (14%) | catalogued as COSV64763515, COSV64771895; called by muse, mutect2, varscan2
- KIF2B | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs776017105, COSV52129130; called by muse, mutect2, varscan2
- KLHL32 | c.1098G>C p.R366S | Missense Mutation (SNP) | VAF 127/379 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.19); catalogued as COSV65114782; called by muse, mutect2, varscan2
- KMT2D | c.5504G>T p.R1835L | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.165); catalogued as rs368134008; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT17 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 167/620 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs754643287; called by muse, mutect2, varscan2
- KRT28 | c.1247C>A p.S416Y | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.092); catalogued as COSV60683397; called by muse, mutect2, varscan2
- KRT3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 99/345 reads (29%) | catalogued as rs754256275; called by muse, mutect2, varscan2
- KRTAP26-1 | c.219del p.G74Afs*52 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | catalogued as COSV62128886; called by mutect2, pindel, varscan2
- LAMA5 | c.6064C>T p.R2022W | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs753064723; called by muse, mutect2, varscan2
- LAMB1 | c.4237G>A p.G1413R | Missense Mutation (SNP) | VAF 169/675 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369198991; called by muse, mutect2, varscan2
- LCE1A | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.994); catalogued as COSV58727469; called by muse, mutect2
- LGI3 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 172/747 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs756605767; called by muse, mutect2, varscan2
- LILRB1 | c.632G>T p.R211L (on ENST00000427581; = p.R175L on NM_006669.6) | Missense Mutation (SNP) | VAF 370/822 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV61116962, COSV61117136, COSV61121229; called by muse, varscan2
- LIMS2 | c.607C>T p.R203W (on ENST00000355119 / NM_001161403.3; = p.R227W on NM_017980.4) | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745911673; called by muse, mutect2, varscan2
- LMO4 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65170642; called by muse, mutect2, varscan2
- LRRC8E | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 51/281 reads (18%) | catalogued as COSV100143019; called by muse, mutect2, varscan2
- LSR | c.1290C>T p.A430= (on ENST00000361790; = p.A411= on NM_015925.6) | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as rs938435775; called by muse, mutect2, varscan2
- LVRN | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs866648934; called by muse, mutect2, varscan2
- MAGEA12 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 260/866 reads (30%) | catalogued as COSV63294573; called by muse, mutect2, varscan2
- MAGEB3 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV64397030, COSV64397095; called by muse, mutect2, varscan2
- MAGEB3 | c.905C>A p.A302E | Missense Mutation (SNP) | VAF 175/344 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100854843, COSV64396767; called by muse, mutect2, varscan2
- MBD5 | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 262/679 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101289867; called by muse, mutect2, varscan2
- MBL2 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV64758059; called by muse, mutect2, varscan2
- MEPCE | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 42/726 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.061); catalogued as rs1380290276, COSV52769007; called by muse, mutect2
- MKRN3 | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 149/476 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470111765; called by muse, mutect2, varscan2
- MUC16 | c.41078+1G>A p.X13693_splice | Splice Site (SNP) | VAF 283/412 reads (69%) | catalogued as COSV101109998; called by muse, mutect2, varscan2
- MYADM | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 373/592 reads (63%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.68); catalogued as rs1422106309; called by muse, mutect2, varscan2
- MYCN | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 103/147 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0.258); catalogued as COSV55259211, COSV99807993; called by muse, mutect2, varscan2
- MYO7A | c.5719T>C p.Y1907H | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs1358968083; called by muse, mutect2, varscan2
- MYOM2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs752951216; called by muse, mutect2, varscan2
- NAA25 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 48/349 reads (14%) | catalogued as COSV55706272; called by muse, mutect2, varscan2
- NAALADL2 | c.2193C>G p.N731K | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101495209; called by muse, mutect2, varscan2
- NAV3 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV57072450; called by muse, mutect2, varscan2
- NBEAL1 | c.4369G>C p.E1457Q | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV71373959, COSV71375096; called by muse, mutect2
- NBPF10 | c.10735G>A p.D3579N | Missense Mutation (SNP) | VAF 81/800 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs587609631; called by muse, mutect2, varscan2
- NCR1 | c.831G>A p.W277* | Nonsense Mutation (SNP) | VAF 57/361 reads (16%) | catalogued as COSV99400934; called by muse, mutect2, varscan2
- NEK11 | c.1921C>A p.L641I | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV101273170; called by muse, varscan2
- NLRP3 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 195/309 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60220096; called by muse, mutect2, varscan2
- NLRP5 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66763412; called by muse, mutect2
- NOB1 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1394647849; called by muse, mutect2
- NOS2 | c.3060T>A p.D1020E | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs771057657; called by muse, varscan2
- NOTCH1 | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs752551426; called by muse, mutect2, varscan2
- NOX3 | c.1385G>C p.R462P | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV50150104, COSV99343539; called by muse, mutect2, varscan2
- NPAP1 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV61507839; called by muse, mutect2, varscan2
- NPSR1 | c.1120del p.A374Lfs*? | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | catalogued as COSV63103023; called by mutect2, varscan2
- NT5C1A | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 22/509 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.05); catalogued as COSV52496759; called by muse, mutect2
- NUP37 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51837526; called by muse, mutect2, varscan2
- OPCML | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 149/356 reads (42%) | catalogued as COSV59441089; called by muse, mutect2, varscan2
- OPHN1 | c.1720C>G p.P574A | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV62780855; called by muse, mutect2
- OR10A7 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 100/352 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV58278308, COSV58278754; called by muse, varscan2
- OR11H4 | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59560855; called by muse, mutect2, varscan2
- OR2A5 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 371/708 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs756784012, COSV68738565; called by muse, mutect2, varscan2
- OR2M7 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.566); catalogued as COSV58740816; called by muse, mutect2
- OR5AP2 | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs1461286025, COSV57257255; called by muse, mutect2, varscan2
- OR5B17 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV62160477; called by muse, mutect2, varscan2
- OR5D18 | c.344T>A p.L115* | Nonsense Mutation (SNP) | VAF 22/342 reads (6%) | catalogued as COSV100450538; called by muse, mutect2
- OR5L2 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV65724662; called by muse, mutect2
- OR5R1 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV56572466; called by muse, mutect2
- OR6F1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1411122637; called by muse, mutect2
- OR6K3 | c.464G>T p.R155L (on ENST00000368146; = p.R139L on NM_001005327.2) | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV63745708, COSV63746370; called by muse, mutect2
- OR6N2 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 177/307 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100210485; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1059A>T p.E353D (on ENST00000374531 / NM_001037293.2; = p.E385D on NM_053016.6) | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV57129324; called by muse, mutect2
- PCDH10 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV52103718; called by muse, mutect2, varscan2
- PCDH9 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.828); catalogued as COSV100119593, COSV60583607; called by muse, mutect2
- PCDHA7 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 38/455 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.097); catalogued as COSV65345181; called by muse, mutect2
- PI4KA | c.6152G>T p.G2051V | Missense Mutation (SNP) | VAF 156/696 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55408071; called by mutect2, varscan2
- POLG | c.2244G>T p.W748C | Missense Mutation (SNP) | VAF 57/572 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as CM157496; called by muse, mutect2, varscan2
- POLG | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 150/443 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs185645212, CM095813, COSV51523789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEC | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 60/1090 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.11); catalogued as COSV100742842, COSV62805417; called by muse, mutect2
- PTH2R | c.1337G>C p.R446P | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV55915061; called by muse, mutect2, varscan2
- PXDNL | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62483251; called by mutect2, varscan2
- RBMXL3 | c.1503C>G p.S501R | Missense Mutation (SNP) | VAF 122/238 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV57749876; called by muse, mutect2, varscan2
- RFX7 | c.22C>A p.Q8K (on ENST00000559447 / NM_001368074.1; = p.Q105K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57962392; called by muse, mutect2, varscan2
- RNF125 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs759692910; called by muse, mutect2, varscan2
- RYR3 | c.4736C>T p.A1579V | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs548311351, COSV101212844; called by muse, mutect2, varscan2
- RYR3 | c.12573C>A p.F4191L (on ENST00000389232; = p.F4192L on NM_001036.6) | Missense Mutation (SNP) | VAF 189/410 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV66809467; called by muse, mutect2, varscan2
- SBDS | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 62/630 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1197945757; called by muse, mutect2
- SBNO1 | c.1645C>G p.L549V (on ENST00000420886; = p.L548V on NM_018183.5) | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99929629; called by muse, mutect2
- SIRPG | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/431 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV53808429; called by muse, mutect2
- SLC12A5 | c.2893C>T p.R965W (on ENST00000454036 / NM_001134771.2; = p.R942W on NM_020708.5) | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs1267557723; called by muse, mutect2
- SLC29A3 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 50/419 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1207899993; called by muse, mutect2, varscan2
- SLITRK4 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62024856; called by muse, mutect2, varscan2
- SMLR1 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1448318617; called by muse, mutect2
- SP140 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV59447483; called by muse, mutect2
- SP6 | c.1080dup p.G361Rfs*78 | Frame Shift Ins (INS) | VAF 144/309 reads (47%) | catalogued as rs768829645; called by mutect2, pindel, varscan2
- SPAM1 | c.911C>A p.T304N | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as rs778138042; called by muse, mutect2, varscan2
- SULT2B1 | c.871G>A p.E291K (on ENST00000201586 / NM_177973.2; = p.E276K on NM_004605.2) | Missense Mutation (SNP) | VAF 294/476 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs1185409960, COSV52374914; called by muse, mutect2, varscan2
- SUN5 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781209729; called by muse, mutect2, varscan2
- TBC1D22A | c.688A>G p.M230V | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs144042293; called by muse, mutect2, varscan2
- TBX10 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56876521; called by muse, mutect2
- TBX5 | c.1461C>G p.F487L | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV59865362; called by muse, mutect2
- TDO2 | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.268); catalogued as COSV72233123; called by muse, mutect2, varscan2
- TDRD15 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756026218, COSV68266709; called by muse, mutect2, varscan2
- TGFBI | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs754155367; called by muse, mutect2, varscan2
- THOC2 | c.2254G>C p.G752R | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV55555163; called by muse, mutect2
- TKTL2 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 165/334 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1361260714, COSV54921427; called by muse, mutect2, varscan2
- TLE3 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV58168088; called by muse, varscan2
- TLR2 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770658906; called by muse, mutect2, varscan2
- TLR8 | c.413C>A p.P138H (on ENST00000218032 / NM_138636.5; = p.P156H on NM_016610.4) | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs1231166125; called by muse, mutect2, varscan2
- TMPRSS5 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 49/353 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371532853; called by muse, mutect2, varscan2
- TNXB | c.10409del p.G3470Afs*51 (on ENST00000647633; = p.G3223Afs*51 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 118/412 reads (29%) | catalogued as rs773500008; called by mutect2, pindel, varscan2
- TPO | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 15/192 reads (8%) | catalogued as COSV61103030; called by muse, mutect2
- TRAM1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51598079; called by muse, mutect2, varscan2
- TRAPPC10 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs371379591; called by muse, mutect2
- TRPS1 | c.649C>G p.P217A (on ENST00000220888 / NM_001330599.2; = p.P230A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/661 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV55241015; called by muse, mutect2, varscan2
- TRPV6 | c.944C>G p.S315W | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63890443; called by muse, mutect2, varscan2
- TSC22D4 | c.271A>T p.T91S | Missense Mutation (SNP) | VAF 356/747 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100278828; called by muse, mutect2, varscan2
- TTN | c.42977C>A p.A14326E (on ENST00000591111; = p.A6902E on NM_003319.4) | Missense Mutation (SNP) | VAF 60/723 reads (8%) | PolyPhen benign (0.009); catalogued as rs1553707943; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.11188G>T p.E3730* (on ENST00000591111; = p.E3684* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/474 reads (7%) | catalogued as COSV59861875; called by muse, mutect2
- TTN | c.9395G>A p.G3132E (on ENST00000591111; = p.G3086E on NM_003319.4) | Missense Mutation (SNP) | VAF 34/764 reads (4%) | PolyPhen probably damaging (1); catalogued as rs1293502713, COSV100617625, COSV59893010; called by muse, mutect2
- TTN | c.1696A>G p.M566V | Missense Mutation (SNP) | VAF 284/695 reads (41%) | PolyPhen benign (0); catalogued as rs987302368; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXLNA | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV65314858; called by muse, mutect2
- TYW1B | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as rs781885537; called by muse, mutect2, varscan2
- UBQLN3 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV61165122; called by muse, mutect2
- UBQLN3 | c.325A>C p.T109P | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61165477; called by muse, mutect2, varscan2
- UBTFL1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 202/802 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs555901313; called by muse, varscan2
- UHRF1 | c.895G>T p.G299W (on ENST00000612630 / NM_001290050.1; = p.G312W on NM_013282.4) | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746199151, COSV99503675; called by muse, mutect2, varscan2
- ULK1 | c.725+1G>T p.X242_splice | Splice Site (SNP) | VAF 48/182 reads (26%) | catalogued as COSV100416831; called by muse, mutect2, varscan2
- USH2A | c.11155C>A p.R3719S | Missense Mutation (SNP) | VAF 44/525 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as rs758951363; called by muse, mutect2
- USP17L7 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 320/1472 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs766360987; called by muse, varscan2
- VAV3 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as COSV58393316; called by muse, mutect2, varscan2
- WDR17 | c.3072T>G p.C1024W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54571916; called by muse, mutect2
- WDR64 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV63793143, COSV63796095; called by muse, mutect2
- WWP1 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1020503609; called by muse, mutect2, varscan2
- XAF1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs150987933; called by muse, mutect2
- XIRP2 | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs780403837, COSV54695932, COSV99746418; called by muse, mutect2, varscan2
- XIRP2 | c.2245A>T p.I749F (on ENST00000628543; = p.I924F on NM_152381.6) | Missense Mutation (SNP) | VAF 151/313 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772461489; called by muse, mutect2, varscan2
- ZAP70 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 57/327 reads (17%) | catalogued as COSV53856533; called by muse, mutect2, varscan2
- ZFHX4 | c.8375G>A p.G2792E | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV51494727; called by muse, mutect2, varscan2
- ZNF24 | c.465G>C p.M155I | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54349266, COSV99734328; called by muse, mutect2, varscan2
- ZNF33A | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.76); catalogued as COSV100276319; called by muse, mutect2, varscan2
- ZNF444 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.371); catalogued as rs867836392; called by muse, mutect2, varscan2
- ZNF676 | c.599C>A p.S200Y (on ENST00000650058; = p.S168Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV68093188; called by muse, mutect2
- ZNF677 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 206/480 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61720851; called by muse, mutect2, varscan2
- ZNF75D | c.991C>G p.R331G | Missense Mutation (SNP) | VAF 218/555 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV66132609; called by muse, mutect2, varscan2
- A2ML1 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 30/375 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABCA13 | c.6064C>A p.L2022I | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); called by muse, mutect2
- ABCA13 | c.14250T>G p.F4750L | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ABCC11 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- AC048338.2 | c.72C>G p.Y24* | Nonsense Mutation (SNP) | VAF 29/560 reads (5%) | called by muse, mutect2
- AC127029.3 | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 282/608 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ACSM1 | c.1046C>G p.P349R | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ADCY3 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 91/134 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADCYAP1 | c.11_21del p.C4* | Frame Shift Del (DEL) | VAF 52/222 reads (23%) | called by mutect2, pindel, varscan2
- ADGB | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADRA2A | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.976); called by muse, mutect2
- ADRB3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- AGBL4 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 108/438 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- AGL | c.3326G>T p.G1109V | Missense Mutation (SNP) | VAF 148/496 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANGPTL3 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANK1 | c.4104+1G>C p.X1368_splice | Splice Site (SNP) | VAF 115/462 reads (25%) | called by muse, mutect2, varscan2
- ANK2 | c.8078C>A p.S2693Y | Missense Mutation (SNP) | VAF 175/575 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKMY1 | c.2780T>G p.V927G | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- ANKRD34C | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 133/430 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ANKRD52 | c.2926G>C p.V976L | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.208); called by muse, mutect2
- ANO5 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 173/439 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO6 | c.2717G>T p.R906L | Missense Mutation (SNP) | VAF 128/398 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by mutect2, varscan2
- APEX1 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 305/447 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.2195A>T p.K732M | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- APOBEC3F | c.1062G>T p.W354C | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARFGEF3 | c.4289C>G p.S1430* | Nonsense Mutation (SNP) | VAF 86/292 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.2922A>T p.K974N | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP33 | c.1796_1797insT p.S602Qfs*47 | Frame Shift Ins (INS) | VAF 56/164 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 107/475 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP40 | c.863T>G p.V288G | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ARHGEF6 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 228/609 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ARHGEF9 | c.1376A>T p.N459I | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARID1A | c.6758T>C p.L2253P | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2
- ASPM | c.1412A>C p.K471T | Missense Mutation (SNP) | VAF 112/394 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, varscan2
- ATF7IP | c.1797A>G p.I599M | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ATG2A | c.2380G>T p.D794Y | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP10A | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP12A | c.1541A>C p.H514P | Missense Mutation (SNP) | VAF 154/218 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP4A | c.2094G>C p.E698D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B4 | c.88-2A>G p.X30_splice | Splice Site (SNP) | VAF 21/376 reads (6%) | called by muse, mutect2
- AURKC | c.464C>A p.T155N (on ENST00000302804 / NM_001015878.2; = p.T121N on NM_003160.3) | Missense Mutation (SNP) | VAF 134/909 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- B3GNT2 | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2
- BAIAP2L1 | c.486+1G>A p.X162_splice | Splice Site (SNP) | VAF 157/308 reads (51%) | called by muse, mutect2, varscan2
- BANP | c.1340G>T p.G447V (on ENST00000286122; = p.G419V on NM_079837.3) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BBS2 | c.1527+7A>G | Splice Region (SNP) | VAF 28/438 reads (6%) | called by muse, mutect2
- BDKRB2 | c.420C>A p.N140K | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB4 | c.167del p.L56Wfs*177 | Frame Shift Del (DEL) | VAF 128/383 reads (33%) | called by mutect2, pindel, varscan2
- BSN | c.7276G>A p.V2426M | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BTN2A1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 145/497 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); called by muse, varscan2
- C1orf167 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C2CD2L | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- C5 | c.3107C>G p.S1036C | Missense Mutation (SNP) | VAF 170/323 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, varscan2
- C7orf31 | c.1270T>A p.Y424N | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.509); called by muse, mutect2
- C9orf50 | c.1087A>T p.M363L | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CABP7 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CACNA1F | c.4468C>A p.Q1490K | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CADPS | c.2099G>T p.C700F | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMSAP2 | c.424_438del p.T142_A146del | In Frame Del (DEL) | VAF 67/126 reads (53%) | called by mutect2, pindel, varscan2
- CASK | c.1855G>C p.A619P | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CASZ1 | c.4844G>T p.S1615I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.074); called by muse, mutect2
- CCDC113 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 106/351 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC168 | c.20651C>G p.S6884* | Nonsense Mutation (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2, varscan2
- CCDC173 | c.323A>T p.K108I | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC80 | c.2498C>A p.P833Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42EP2 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH10 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 24/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CDK5RAP2 | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2
- CEACAM18 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2
- CEP126 | c.3317G>C p.R1106T | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP47 | c.8242G>T p.D2748Y | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CFH | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 169/314 reads (54%) | SIFT tolerated (1); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CHD7 | c.2840G>T p.R947L | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CHRNB1 | c.1020C>A p.H340Q | Missense Mutation (SNP) | VAF 218/338 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHST9 | c.856T>G p.L286V | Missense Mutation (SNP) | VAF 140/461 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLEC4D | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMTR1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CNGA4 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 79/538 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGB3 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 117/416 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CNTROB | c.2225_2226insT p.S743Ifs*33 | Frame Shift Ins (INS) | VAF 103/233 reads (44%) | called by mutect2, pindel, varscan2
- COL12A1 | c.7215G>T p.K2405N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- COL14A1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL24A1 | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A2 | c.2958_2960del p.T987del | In Frame Del (DEL) | VAF 62/203 reads (31%) | called by pindel, varscan2
- CPNE8 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- CPZ | c.1744del p.Q582Nfs*60 (on ENST00000360986 / NM_001014447.3; = p.Q571Nfs*60 on NM_003652.3) | Frame Shift Del (DEL) | VAF 60/251 reads (24%) | called by mutect2, pindel, varscan2
- CSMD1 | c.9773G>T p.C3258F (on ENST00000520002; = p.C3257F on NM_033225.6) | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSMD1 | c.9346T>C p.W3116R (on ENST00000520002; = p.W3115R on NM_033225.6) | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSMD2 | c.6296C>T p.S2099L | Missense Mutation (SNP) | VAF 162/422 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.3965G>C p.S1322T (on ENST00000297405 / NM_001363185.1; = p.S1218T on NM_052900.3) | Missense Mutation (SNP) | VAF 125/682 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CSNK1G3 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- CTDP1 | c.2628G>C p.K876N | Missense Mutation (SNP) | VAF 161/446 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CTSE | c.81del p.R28Gfs*26 | Frame Shift Del (DEL) | VAF 35/233 reads (15%) | called by mutect2, pindel, varscan2
- CWC22 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- CYB5R4 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CYP11B1 | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 251/1249 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DAB1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- DAG1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 63/648 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- DCAF12L1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 130/248 reads (52%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.726); called by muse, varscan2
- DEFB110 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEPDC4 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DGKH | c.2535A>G p.I845M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKI | c.2583G>T p.Q861H | Missense Mutation (SNP) | VAF 150/273 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- DHTKD1 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 129/516 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DIP2B | c.2674G>T p.G892W | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DISP3 | c.1777T>C p.F593L | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DMD | c.10785G>C p.Q3595H | Missense Mutation (SNP) | VAF 84/669 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DMD | c.6817A>G p.T2273A | Missense Mutation (SNP) | VAF 350/687 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMD | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 65/603 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.3702G>A p.M1234I | Missense Mutation (SNP) | VAF 43/460 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- DNAJC3 | c.1093A>T p.T365S | Missense Mutation (SNP) | VAF 91/133 reads (68%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC4 | c.615-23_621del p.X205_splice | Splice Site (DEL) | VAF 116/661 reads (18%) | called by mutect2, pindel
- DOCK7 | c.1390C>G p.P464A | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOP1B | c.5266C>G p.P1756A | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DPY19L3 | c.301A>C p.M101L | Missense Mutation (SNP) | VAF 26/419 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.851); called by muse, mutect2
- EIF3B | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 179/331 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- EML5 | c.2594C>T p.T865I | Missense Mutation (SNP) | VAF 189/348 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EP400 | c.3247G>C p.G1083R | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- EPB41L3 | c.2124G>T p.S708= | Splice Region (SNP) | VAF 96/257 reads (37%) | called by muse, mutect2, varscan2
- ERI3 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- ERVMER34-1 | c.1178A>G p.K393R | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); called by muse, mutect2
- ESPL1 | c.3527A>G p.H1176R | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ETV6 | c.1307A>T p.H436L | Missense Mutation (SNP) | VAF 110/329 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EYS | c.3712G>A p.D1238N | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- F8 | c.5940T>A p.H1980Q | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- FAAH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 77/348 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM151B | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FAM155B | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FAT3 | c.1478C>T p.T493I | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FAT3 | c.7639G>A p.D2547N | Missense Mutation (SNP) | VAF 154/344 reads (45%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.4008_4055del p.M1337_C1352del | In Frame Del (DEL) | VAF 40/418 reads (10%) | called by mutect2, pindel
- FCAMR | c.443C>G p.P148R | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- FCER1A | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FGD1 | c.1802C>A p.S601* | Nonsense Mutation (SNP) | VAF 40/264 reads (15%) | called by muse, varscan2
- FMNL1 | c.970-2A>T p.X324_splice | Splice Site (SNP) | VAF 16/273 reads (6%) | called by muse, mutect2
- FOXD4L4 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 64/452 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- FREM1 | c.4292A>G p.Y1431C | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FSD2 | c.695A>T p.N232I | Missense Mutation (SNP) | VAF 95/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FYCO1 | c.1796A>C p.Q599P | Missense Mutation (SNP) | VAF 119/194 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD1 | c.276_277insTCG p.P92_P93insS | In Frame Ins (INS) | VAF 88/218 reads (40%) | called by pindel, varscan2
- GALK2 | c.1201G>C p.G401R | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALK2 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNTL5 | c.321T>A p.S107R | Missense Mutation (SNP) | VAF 95/490 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GATA3 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCKR | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 445/634 reads (70%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GDAP2 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDAP2 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- GFRA2 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GLIS2 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GLRA3 | c.381del p.W127* | Frame Shift Del (DEL) | VAF 75/175 reads (43%) | called by mutect2, pindel, varscan2
- GLUL | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 164/595 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- GNAS | c.1582C>A p.L528I | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); called by muse, mutect2
- GOLGA6L6 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 46/737 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2
- GPC4 | c.1361C>A p.T454N | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- GPC5 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPER1 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 174/235 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GREB1 | c.4456G>T p.E1486* | Nonsense Mutation (SNP) | VAF 32/166 reads (19%) | called by muse, varscan2
- GRIA1 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- GRID1 | c.2199del p.K734Rfs*18 | Frame Shift Del (DEL) | VAF 58/182 reads (32%) | called by mutect2, pindel, varscan2
- GRIK5 | c.131T>C p.L44S | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GRIN2B | c.3708G>T p.R1236S | Missense Mutation (SNP) | VAF 34/403 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.306); called by muse, mutect2
- GRIPAP1 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GUCY2C | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- HDHD5 | c.1097A>T p.Y366F (on ENST00000336737 / NM_033070.3; = p.Y336F on NM_017829.5) | Missense Mutation (SNP) | VAF 162/617 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- HEATR9 | c.1617C>A p.C539* | Nonsense Mutation (SNP) | VAF 34/534 reads (6%) | called by muse, mutect2
- HGF | c.1366A>T p.N456Y | Missense Mutation (SNP) | VAF 67/558 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HGH1 | c.691C>A p.H231N | Missense Mutation (SNP) | VAF 54/710 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.707); called by muse, mutect2
- HLCS | c.1496C>G p.A499G | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HMCN2 | c.14427C>A p.S4809R | Missense Mutation (SNP) | VAF 68/724 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2
- HNRNPR | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 113/194 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- HOXB7 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- HRH2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 174/478 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HSFX1 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 151/468 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA13 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR3B | c.1219G>T p.V407F | Missense Mutation (SNP) | VAF 213/465 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- HUNK | c.1997T>A p.M666K | Missense Mutation (SNP) | VAF 158/367 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HUWE1 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 46/684 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- HYDIN | c.7502C>G p.P2501R | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IFT80 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); called by muse, mutect2
- IGHV1OR21-1 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 88/488 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, varscan2
- IGHV3-16 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 288/449 reads (64%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLV7-46 | c.195dup p.R66Qfs*6 | Frame Shift Ins (INS) | VAF 114/513 reads (22%) | called by pindel, varscan2
- IL17RA | c.423G>T p.R141= | Splice Region (SNP) | VAF 59/880 reads (7%) | called by muse, mutect2
- ILDR2 | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- INTS4 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 102/283 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INTS6L | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- IQUB | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IRX3 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IRX6 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ITGB5 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITIH6 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR2 | c.2589+2T>A p.X863_splice | Splice Site (SNP) | VAF 82/179 reads (46%) | called by muse, varscan2
- JPH1 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KATNIP | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- KBTBD3 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KCNA4 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- KCNC2 | c.191del p.P64Rfs*91 | Frame Shift Del (DEL) | VAF 75/271 reads (28%) | called by mutect2, pindel, varscan2
- KCNN2 | c.1556G>C p.G519A (on ENST00000264773; = p.G731A on NM_021614.4) | Missense Mutation (SNP) | VAF 119/293 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNQ4 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- KCNU1 | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 142/481 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCTD20 | c.968-9_968delinsTTTTTTTTTT p.X323_splice | Splice Site (ONP) | VAF 21/253 reads (8%) | called by mutect2*, pindel
- KCTD9 | c.163T>G p.L55V | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KHSRP | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIAA0100 | c.6505C>T p.R2169C | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF26A | c.3861T>A p.C1287* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- KLF15 | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHDC4 | c.1025G>T p.W342L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KNDC1 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- KNDC1 | c.4328C>A p.P1443H | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2
- KRT27 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- KRT78 | c.1442del p.G481Afs*26 | Frame Shift Del (DEL) | VAF 154/531 reads (29%) | called by mutect2, pindel, varscan2
- KSR2 | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KYNU | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 61/329 reads (19%) | called by muse, mutect2, varscan2
- KYNU | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L1CAM | c.3108G>T p.W1036C | Missense Mutation (SNP) | VAF 155/526 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LARGE1 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LATS1 | c.3030dup p.K1011* | Frame Shift Ins (INS) | VAF 103/420 reads (25%) | called by mutect2, pindel, varscan2
- LGI1 | c.298T>A p.S100T | Missense Mutation (SNP) | VAF 148/403 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- LINGO2 | c.763T>C p.S255P | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LIPI | c.273_274insT p.N92* | Frame Shift Ins (INS) | VAF 76/434 reads (18%) | called by mutect2, pindel, varscan2
- LPA | c.2568C>A p.H856Q | Missense Mutation (SNP) | VAF 120/741 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP2 | c.237A>T p.Q79H | Missense Mutation (SNP) | VAF 394/845 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- LRRC25 | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 271/424 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LRRC31 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 122/353 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP4 | c.1468C>T p.Q490* (on ENST00000308370 / NM_001042544.1; = p.Q453* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 44/307 reads (14%) | called by muse, mutect2, varscan2
- LVRN | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 40/297 reads (13%) | called by muse, mutect2, varscan2
- LVRN | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MAGEB10 | c.674A>T p.K225I | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- MAGEC3 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 27/453 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.094); called by muse, mutect2
- MAGED1 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MAGEE1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAGI1 | c.2581A>G p.I861V (on ENST00000402939 / NM_001033057.2; = p.I889V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MANBA | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP2 | c.3741A>T p.K1247N | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- MAP7D1 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2
- MAPKBP1 | c.4317+1G>T p.X1439_splice (on ENST00000456763 / NM_001128608.2; = p.X1433_splice on NM_014994.3) | Splice Site (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- MARCHF10 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 38/622 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2
- MDN1 | c.5410G>A p.A1804T | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MEAF6 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MGAM | c.5208C>A p.F1736L | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MGAT3 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MIDN | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 174/341 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MIPEP | c.637T>A p.L213M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- MNDA | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MOG | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 206/459 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MON1B | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRNIP | c.456G>C p.W152C | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MS4A2 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 173/449 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTA1 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2
- MUC16 | c.36886A>G p.T12296A | Missense Mutation (SNP) | VAF 86/141 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC17 | c.9778A>G p.S3260G | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MUC5B | c.6605T>A p.L2202Q | Missense Mutation (SNP) | VAF 84/582 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MUS81 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 31/476 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MYO7B | c.692_693del p.R231Hfs*34 | Frame Shift Del (DEL) | VAF 72/339 reads (21%) | called by pindel, varscan2
- NAALAD2 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAALADL2 | c.646A>C p.N216H | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCAM2 | c.1513A>C p.I505L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA1 | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- NDNF | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.932); called by muse, mutect2
- NEBL | c.1449+1G>T p.X483_splice | Splice Site (SNP) | VAF 211/614 reads (34%) | called by muse, mutect2, varscan2
- NECTIN3 | c.1356G>T p.M452I | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NEDD9 | c.1937A>T p.E646V | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NFE2L2 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- NLRP13 | c.2833G>T p.A945S | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- NLRP13 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 80/521 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- NLRP5 | c.3407C>A p.P1136H | Missense Mutation (SNP) | VAF 148/360 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NLRP8 | c.1472G>T p.S491I | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NOTCH1 | c.4144G>T p.E1382* | Nonsense Mutation (SNP) | VAF 153/178 reads (86%) | called by muse, varscan2
- NPHS1 | c.3390C>A p.V1130= | Splice Region (SNP) | VAF 73/1092 reads (7%) | called by muse, mutect2
- NR4A3 | c.1353G>A p.W451* | Nonsense Mutation (SNP) | VAF 270/486 reads (56%) | called by muse, mutect2, varscan2
- NT5C1B | c.1796T>C p.I599T (on ENST00000359846 / NM_001199086.2; = p.I539T on NM_033253.4) | Missense Mutation (SNP) | VAF 59/83 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUDT9 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUGGC | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NYAP1 | c.2068C>G p.L690V | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.182); called by muse, mutect2
- OCA2 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 236/483 reads (49%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPHN1 | c.2222dup p.V742Sfs*43 | Frame Shift Ins (INS) | VAF 110/277 reads (40%) | called by mutect2, pindel, varscan2
- OPHN1 | c.680A>C p.Q227P | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2
- OR10G8 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 102/492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR10H1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2
- OR11A1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 106/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR14A16 | c.256C>G p.H86D | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- OR2AG1 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 57/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2AJ1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR2AT4 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR2B3 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 112/424 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- OR2L3 | c.328del p.E110Kfs*26 | Frame Shift Del (DEL) | VAF 272/701 reads (39%) | called by mutect2, pindel, varscan2
- OR2T35 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 58/852 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2
- OR4A5 | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 100/406 reads (25%) | called by muse, mutect2, varscan2
- OR4D9 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51S1 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- OR52J3 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR52M1 | c.496del p.R166Afs*22 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- OR5AR1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, varscan2
- OR5R1 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8K3 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.12); called by muse, mutect2
- PABPC5 | c.905T>A p.V302E | Missense Mutation (SNP) | VAF 102/307 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PACS1 | c.577A>C p.M193L | Missense Mutation (SNP) | VAF 161/349 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAFAH1B1 | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.09); called by muse, mutect2
- PAQR3 | c.338dup p.C114Lfs*54 | Frame Shift Ins (INS) | VAF 55/150 reads (37%) | called by mutect2, pindel, varscan2
- PATL1 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA13 | c.1187A>T p.K396M | Missense Mutation (SNP) | VAF 165/351 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PCDHA9 | c.2309T>C p.M770T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- PCDHB7 | c.1552T>A p.S518T | Missense Mutation (SNP) | VAF 56/685 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- PCDHGA5 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PCGF3 | c.621_649del p.E208Vfs*6 | Frame Shift Del (DEL) | VAF 20/232 reads (9%) | called by mutect2, pindel
- PEG10 | c.131T>A p.L44H (on ENST00000482108 / NM_001040152.2; = p.L78H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PEX1 | c.2429C>T p.T810I | Missense Mutation (SNP) | VAF 166/411 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PFKFB1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 26/284 reads (9%) | PolyPhen probably damaging (1); called by muse, mutect2
- PGP | c.170_195del p.R57Hfs*108 | Frame Shift Del (DEL) | VAF 42/244 reads (17%) | called by mutect2, pindel
- PHF21B | c.143T>G p.V48G | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PIEZO2 | c.6122A>T p.E2041V | Missense Mutation (SNP) | VAF 179/466 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PIK3C2G | c.1730dup p.L577Ffs*6 | Frame Shift Ins (INS) | VAF 56/178 reads (31%) | called by mutect2, pindel, varscan2
- PIK3CA | c.3205T>A p.*1069Rext*4 | Nonstop Mutation (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- PIK3CG | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 106/186 reads (57%) | called by muse, mutect2, varscan2
- PKP3 | c.2200A>T p.I734F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- PLAC1 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.359); called by muse, mutect2
- PLAU | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PLCE1 | c.3253A>G p.K1085E | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- PLEKHM3 | c.474C>G p.D158E | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- PLP2 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 89/551 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PLXNC1 | c.656A>C p.E219A | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- POLD1 | c.1031_1032insC p.W344Cfs*291 | Frame Shift Ins (INS) | VAF 69/457 reads (15%) | called by mutect2, pindel, varscan2
- POLE | c.4907A>G p.Y1636C | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- POLR1B | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- POLR3B | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 152/456 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLR3C | c.111A>C p.R37S | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PPFIA2 | c.2197G>C p.A733P | Missense Mutation (SNP) | VAF 192/450 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP4R3A | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PPP6R1 | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 47/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PRDM16 | c.1975C>G p.P659A | Missense Mutation (SNP) | VAF 126/148 reads (85%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRODH2 | c.124A>T p.S42C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- PRPF40A | c.2609A>T p.D870V | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.194); called by muse, mutect2
- PRR27 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PRSS1 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 248/724 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, varscan2
- PSMD2 | c.2273A>T p.N758I | Missense Mutation (SNP) | VAF 22/531 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); called by muse, mutect2
- PTPRH | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 200/361 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRZ1 | c.618del p.F206Lfs*7 | Frame Shift Del (DEL) | VAF 24/260 reads (9%) | called by mutect2, pindel
- PTX3 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- QPRT | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 113/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- QSOX2 | c.1085A>G p.K362R | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RAD51B | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 93/142 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RAD9A | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- RALGAPA2 | c.4207A>T p.S1403C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RAPSN | c.1182C>G p.N394K | Missense Mutation (SNP) | VAF 63/458 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RARB | c.613C>G p.L205V (on ENST00000383772 / NM_001290216.2; = p.L198V on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/140 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RARB | c.614T>C p.L205P (on ENST00000383772 / NM_001290216.2; = p.L198P on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RASGRP3 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 154/244 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RAX | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- RB1 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- RBBP6 | c.2606A>C p.N869T | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBL1 | c.2524C>G p.Q842E | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RDH16 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 195/653 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RFX6 | c.1848G>T p.Q616H | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS7 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 349/585 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDL1 | c.1079G>C p.R360P (on ENST00000219551 / NM_001318733.2; = p.R295P on NM_001278720.2) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOBTB1 | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPK4 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 111/414 reads (27%) | called by muse, mutect2, varscan2
- RNF222 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RPL10 | c.11_13del p.R4del | In Frame Del (DEL) | VAF 159/712 reads (22%) | called by pindel, varscan2
- RSL24D1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RTL3 | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 153/328 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RYR1 | c.4461G>T p.K1487N | Missense Mutation (SNP) | VAF 24/529 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- RYR1 | c.6109G>T p.D2037Y | Missense Mutation (SNP) | VAF 96/751 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SALL3 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAMD3 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SCAMP3 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- SCN1A | c.4812G>T p.W1604C (on ENST00000303395 / NM_001202435.3; = p.W1593C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDCCAG8 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2
- SEC23IP | c.1574T>G p.I525S | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SEL1L2 | c.552A>C p.A184= | Splice Region (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2
- SERINC2 | c.577G>A p.A193T (on ENST00000373709 / NM_178865.5; = p.A197T on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA5 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SGIP1 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 91/237 reads (38%) | called by muse, mutect2, varscan2
- SGK1 | c.140del p.G47Afs*50 | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | called by mutect2, pindel, varscan2
- SH2D1B | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 178/338 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.2872C>G p.R958G | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SI | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SIPA1L3 | c.3439G>C p.G1147R | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2
- SIRPB1 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.209); called by muse, mutect2
- SKIL | c.1294A>T p.K432* | Nonsense Mutation (SNP) | VAF 67/288 reads (23%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1100C>A p.A367E | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- SLC22A23 | c.1113G>C p.M371I | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC34A3 | c.1658_1669del p.P553_L556del | In Frame Del (DEL) | VAF 70/398 reads (18%) | called by mutect2, varscan2
- SLC44A1 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 88/434 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SLC47A1 | c.1591C>G p.P531A | Missense Mutation (SNP) | VAF 110/3982 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- SLC47A2 | c.1433T>A p.V478D | Missense Mutation (SNP) | VAF 58/1986 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- SLC4A4 | c.1865A>C p.N622T (on ENST00000264485 / NM_001098484.3; = p.N578T on NM_003759.4) | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC5A6 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC5A8 | c.1233G>C p.Q411H | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC7A13 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- SLCO1A2 | c.1611G>T p.R537S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLF1 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLITRK4 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCD2 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SMYD1 | c.274del p.A92Pfs*85 | Frame Shift Del (DEL) | VAF 46/85 reads (54%) | called by mutect2, pindel, varscan2
- SNED1 | c.2833T>C p.Y945H | Missense Mutation (SNP) | VAF 133/351 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SOAT2 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 114/323 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORBS1 | c.3416G>A p.G1139D | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SP140 | c.1904C>A p.A635E | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SP8 | c.641G>C p.G214A (on ENST00000361443 / NM_198956.4; = p.G232A on NM_182700.6) | Missense Mutation (SNP) | VAF 125/194 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- SPATA16 | c.1343G>C p.S448T | Missense Mutation (SNP) | VAF 23/504 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- SPATA31E1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 220/390 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SRCAP | c.2174A>T p.Y725F | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRSF6 | c.644G>C p.R215T | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STK31 | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 141/221 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STMND1 | c.723del p.K242Rfs*8 | Frame Shift Del (DEL) | VAF 78/354 reads (22%) | called by mutect2, pindel, varscan2
- STRN4 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STX10 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 211/314 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SUCNR1 | c.209T>A p.L70* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- SURF6 | c.393+1G>T p.X131_splice | Splice Site (SNP) | VAF 71/270 reads (26%) | called by muse, mutect2, varscan2
- SYNE1 | c.26357C>T p.P8786L (on ENST00000367255 / NM_182961.4; = p.P8738L on NM_033071.3) | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.18637C>T p.Q6213* (on ENST00000367255 / NM_182961.4; = p.Q6142* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 46/771 reads (6%) | called by muse, mutect2
- SYNE1 | c.12112C>A p.H4038N (on ENST00000367255 / NM_182961.4; = p.H3967N on NM_033071.3) | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SYT6 | c.1181C>G p.T394R (on ENST00000610222 / NM_001366225.1; = p.T309R on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TAB3 | c.1516A>G p.S506G | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TAS2R9 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 99/339 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBXT | c.493A>T p.K165* | Nonsense Mutation (SNP) | VAF 174/581 reads (30%) | called by muse, mutect2, varscan2
- TBXT | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TDRD12 | c.2608A>T p.R870W (on ENST00000444215; = p.R875W on NM_001366102.1) | Missense Mutation (SNP) | VAF 159/325 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TEKT4 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- TEX13C | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 105/367 reads (29%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TFAP2A | c.484C>T p.P162S (on ENST00000482890; = p.P154S on NM_001032280.3) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- TFR2 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2
- TGFBR3 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- THOC2 | c.4721G>T p.R1574L | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- TLN2 | c.973A>T p.K325* | Nonsense Mutation (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- TM2D3 | c.301G>T p.A101S (on ENST00000333202 / NM_078474.3; = p.A75S on NM_025141.3) | Missense Mutation (SNP) | VAF 243/460 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2
- TMEM218 | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TMEM71 | c.486dup p.A163Cfs*3 (on ENST00000523829 / NM_001382398.1; = p.A144Cfs*3 on NM_144649.3) | Frame Shift Ins (INS) | VAF 45/224 reads (20%) | called by mutect2, pindel
- TMEM86A | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 93/198 reads (47%) | called by muse, mutect2, varscan2
- TMEM87B | c.1378T>C p.Y460H | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMPRSS13 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 226/556 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMPRSS13 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 228/560 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TNN | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2
- TNR | c.3492A>T p.L1164F | Missense Mutation (SNP) | VAF 270/424 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TNRC18 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- TRAK1 | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TRIM10 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.038); called by muse, mutect2
- TRIM33 | c.3185T>C p.V1062A | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- TRPV2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- TSPAN9 | c.538A>C p.N180H | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.071); called by muse, mutect2
- TTN | c.60398T>A p.V20133E (on ENST00000591111; = p.V12709E on NM_003319.4) | Missense Mutation (SNP) | VAF 62/170 reads (36%) | PolyPhen benign (0.399); called by muse, varscan2
- TTN | c.25151A>G p.H8384R (on ENST00000591111; = p.H7457R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/343 reads (41%) | PolyPhen benign (0.125); called by muse, mutect2
- TUBA3D | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TUBB4B | c.64del p.E22Rfs*2 | Frame Shift Del (DEL) | VAF 425/694 reads (61%) | called by mutect2, pindel, varscan2
- U2SURP | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBQLNL | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UBTFL1 | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 72/626 reads (12%) | called by muse, varscan2
- UBTFL1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 75/630 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, varscan2
- UGT8 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ULK2 | c.1465A>T p.S489C | Missense Mutation (SNP) | VAF 67/1003 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- UNC13A | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 162/238 reads (68%) | called by muse, varscan2
- UNC93A | c.1197C>A p.F399L | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UPB1 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 349/822 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UPK1A | c.462G>C p.M154I | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- UPK1B | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- URB2 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- USH2A | c.4639A>T p.S1547C | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- USH2A | c.2035G>T p.G679* | Nonsense Mutation (SNP) | VAF 182/308 reads (59%) | called by muse, mutect2, varscan2
- USH2A | c.1833C>G p.N611K | Missense Mutation (SNP) | VAF 40/508 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- USP17L7 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 318/1427 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- USP27X | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- USP33 | c.1904T>G p.F635C | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP37 | c.2121G>T p.E707D | Missense Mutation (SNP) | VAF 168/281 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- VNN1 | c.664A>T p.T222S | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- VNN2 | c.472T>A p.Y158N | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- VWA5B1 | c.604T>A p.W202R | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- WDFY4 | c.2509A>T p.M837L | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2
- WDR12 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR17 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR19 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR64 | c.752A>G p.Q251R | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.177); called by muse, mutect2
- WDR64 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2
- WWP1 | c.1953del p.D652Tfs*36 | Frame Shift Del (DEL) | VAF 68/208 reads (33%) | called by mutect2, pindel*, varscan2
- XPO4 | c.2698G>C p.D900H | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- YTHDC2 | c.*6A>T | Splice Region (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- ZAP70 | c.974T>A p.L325H | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, varscan2
- ZBED4 | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZBTB18 | c.1187A>G p.Q396R | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ZC2HC1A | c.353-1G>C p.X118_splice | Splice Site (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1930C>A p.L644I | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFPM2 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 106/1288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFR2 | c.1981A>T p.I661F | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZGRF1 | c.5662A>T p.N1888Y | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZIC5 | c.1764C>A p.Y588* | Nonsense Mutation (SNP) | VAF 139/204 reads (68%) | called by muse, mutect2, varscan2
- ZKSCAN3 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ZNF274 | c.905G>T p.G302V (on ENST00000610905; = p.G197V on NM_016324.3) | Missense Mutation (SNP) | VAF 101/178 reads (57%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ZNF285 | c.241A>T p.I81F | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ZNF311 | c.1786T>A p.S596T | Missense Mutation (SNP) | VAF 210/413 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ZNF354A | c.652_653del p.L218Vfs*2 | Frame Shift Del (DEL) | VAF 26/248 reads (10%) | called by mutect2, varscan2
- ZNF358 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF37A | c.1625A>G p.Q542R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF415 | c.732T>A p.Y244* | Nonsense Mutation (SNP) | VAF 61/444 reads (14%) | called by muse, mutect2, varscan2
- ZNF451 | c.864A>T p.K288N | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ZNF469 | c.6524_6525insT p.C2176Lfs*93 (on ENST00000437464; = p.C2204Lfs*93 on NM_001367624.2) | Frame Shift Ins (INS) | VAF 88/366 reads (24%) | called by mutect2, pindel*, varscan2
- ZNF519 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.244); called by muse, mutect2
- ZNF536 | c.1396C>A p.L466M | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2
- ZNF556 | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 272/399 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF556 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 271/398 reads (68%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- ZNF578 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 193/362 reads (53%) | called by muse, varscan2
- ZNF578 | c.1686C>A p.S562R | Missense Mutation (SNP) | VAF 165/304 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, varscan2
- ZNF676 | c.601T>G p.Y201D (on ENST00000650058; = p.Y169D on NM_001001411.3) | Missense Mutation (SNP) | VAF 136/269 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF71 | c.363del p.M122Cfs*24 | Frame Shift Del (DEL) | VAF 70/429 reads (16%) | called by mutect2, pindel, varscan2
- ZNF737 | c.887G>C p.R296P | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ZNF775 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ZNF99 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ABCB4 | c.1687T>C p.L563= | Silent (SNP) | VAF 122/574 reads (21%) | catalogued as rs370315075; called by muse, mutect2, varscan2
- ABCB5 | c.1998C>G p.T666= (on ENST00000404938 / NM_001163941.2; = p.T221= on NM_178559.6) | Silent (SNP) | VAF 94/179 reads (53%) | catalogued as rs138914290; called by muse, mutect2, varscan2
- ABL1 | c.2076G>T p.T692= | Silent (SNP) | VAF 158/229 reads (69%) | called by muse, mutect2, varscan2
- ABTB2 | c.2181C>T p.H727= | Silent (SNP) | VAF 109/397 reads (27%) | catalogued as rs770356882; called by muse, mutect2, varscan2
- AC100868.1 | c.93T>C p.P31= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs1221572271; called by muse, mutect2, varscan2
- ADAM29 | c.1179C>T p.D393= | Silent (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.513C>T p.C171= | Silent (SNP) | VAF 325/901 reads (36%) | called by muse, mutect2, varscan2
- ADCY5 | c.1017C>T p.I339= | Silent (SNP) | VAF 21/323 reads (7%) | catalogued as rs976944993; called by muse, mutect2
- ADCYAP1 | c.303C>T p.A101= | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as rs1178320842; called by muse, mutect2, varscan2
- ADGRA2 | c.3726G>A p.L1242= | Silent (SNP) | VAF 118/278 reads (42%) | called by muse, mutect2, varscan2
- AFF2 | c.759A>G p.L253= | Silent (SNP) | VAF 195/480 reads (41%) | called by muse, mutect2, varscan2
- AFF2 | c.1281G>T p.L427= | Silent (SNP) | VAF 81/373 reads (22%) | called by muse, mutect2, varscan2
- AGRN | c.6099C>T p.A2033= | Silent (SNP) | VAF 673/849 reads (79%) | catalogued as rs376910478; called by muse, mutect2, varscan2
- ALDH16A1 | c.1143C>G p.P381= | Silent (SNP) | VAF 234/358 reads (65%) | called by muse, mutect2, varscan2
- AMPD3 | c.489G>A p.E163= (on ENST00000396553 / NM_001025389.2; = p.E172= on NM_000480.3) | Silent (SNP) | VAF 21/313 reads (7%) | called by muse, mutect2
- ANG | c.369G>C p.G123= | Silent (SNP) | VAF 142/437 reads (32%) | called by muse, mutect2, varscan2
313 further variants in this file (0 protein-altering or splice-affecting, 210 silent, 103 other) are not listed here.
